Somatic mutation profile of tumor specimen C3N-03614-01 (aliquot CPT0194590010) from CPTAC case C3N-03614, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.3 years (27,854 days).
Specimen C3N-03614-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba0396c8-69a8-48b4-8c77-126a793e671e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03614-71 (Blood Derived Normal), aliquot CPT0194710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63c2a36b-86d0-45c0-a83d-8f746be688c8

The open-access MAF lists 825 somatic variants for this specimen: 540 protein-altering or splice-affecting, 256 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 503, Silent 256, Nonsense Mutation 24, Intron 14, 5'Flank 6, Splice Region 6, 3'UTR 5, Splice Site 4, 5'UTR 2, RNA 2, Translation Start Site 2, Frame Shift Del 1.

Variants (750 of 825; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 99/376 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs11547328, CM960267, COSV56984534, COSV56985244; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 175/467 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72651658, CM940291, COSV56809727; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 117/441 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- KCNQ1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 51/488 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs149089817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 33/301 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 79/297 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT4 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV100412783; called by muse, mutect2
- ACTRT2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs541837585, COSV65760607; called by muse, mutect2, varscan2
- ACY3 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV99079452; called by muse, mutect2, varscan2
- ADAM19 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 31/423 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs200894535, COSV57422260; called by muse, mutect2
- ADGRL4 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV66062996; called by muse, mutect2, varscan2
- AHCTF1 | c.2462C>T p.S821F (on ENST00000366508; = p.S795F on NM_015446.5) | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV58252610; called by muse, mutect2, varscan2
- AHNAK2 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 303/827 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60925775; called by muse, mutect2, varscan2
- AIRE | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1414593; called by muse, mutect2, varscan2
- ALDH8A1 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 110/386 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV55641878, COSV99665010; called by muse, mutect2, varscan2
- AMIGO1 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 234/574 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1277235400; called by muse, mutect2, varscan2
- ANKRD30A | c.802C>T p.H268Y (on ENST00000611781; = p.H212Y on NM_052997.2) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1167241084, COSV64610990; called by muse, mutect2, varscan2
- ANKS1B | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61382199; called by muse, mutect2, varscan2
- ANXA7 | c.689C>T p.S230F (on ENST00000372919 / NM_001320880.2; = p.S208F on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.374); catalogued as rs780347653; called by muse, mutect2, varscan2
- AOC2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 142/512 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1370049187; called by muse, mutect2, varscan2
- APBB2 | c.1627G>A p.E543K (on ENST00000295974 / NM_001166050.2; = p.E544K on NM_004307.2) | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs762727771, COSV55956188; called by muse, mutect2, varscan2
- APC | c.6896C>T p.P2299L | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs876658800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP10 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 50/668 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs772472650; called by muse, mutect2
- ARHGEF5 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 87/654 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs564658226, COSV99282579; called by muse, mutect2, varscan2
- ARMC4 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs760572595, COSV100537369; called by muse, mutect2, varscan2
- ARSI | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 65/599 reads (11%) | catalogued as rs1336939929; called by muse, mutect2, varscan2
- ASPH | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62860113; called by mutect2, varscan2
- ATP2B4 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs759460032; called by muse, mutect2, varscan2
- ATP4A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs200791532, COSV52866645; called by muse, mutect2, varscan2
- BCAT1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 41/185 reads (22%) | catalogued as rs754324341, COSV53918429; called by muse, mutect2, varscan2
- BEND4 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs564826071, COSV72469076; called by muse, mutect2, varscan2
- BPTF | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745998280; called by muse, mutect2, varscan2
- BRD7 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs772936465, COSV54271736; called by muse, mutect2, varscan2
- BTN3A2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 33/415 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV100709658; called by muse, mutect2
- C11orf86 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs779314012, COSV100457000, COSV58297178; called by muse, mutect2, varscan2
- CACNA2D4 | c.2778G>A p.M926I | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV54946715, COSV54957121; called by muse, mutect2, varscan2
- CALB1 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV55368249; called by muse, mutect2, varscan2
- CAND2 | c.2065C>T p.P689S (on ENST00000456430 / NM_001162499.2; = p.P596S on NM_012298.3) | Missense Mutation (SNP) | VAF 58/457 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs777087597; called by muse, mutect2, varscan2
- CAPRIN2 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as rs1170197120; called by muse, mutect2, varscan2
- CAT | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 47/334 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs375278815; called by muse, mutect2, varscan2
- CCDC168 | c.15935C>T p.S5312F | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV59418543; called by muse, mutect2, varscan2
- CCDC22 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179683933; called by muse, mutect2, varscan2
- CD163L1 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58018224; called by muse, mutect2, varscan2
- CD180 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 101/535 reads (19%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.826); catalogued as rs1002620673, COSV56519579; called by muse, mutect2, varscan2
- CD244 | c.445G>A p.G149R (on ENST00000368033 / NM_001166663.2; = p.G144R on NM_016382.4) | Missense Mutation (SNP) | VAF 175/721 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1372943314; called by muse, mutect2, varscan2
- CD276 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 63/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562558740, COSV59203915; called by muse, mutect2, varscan2
- CDH22 | c.2099G>A p.G700D | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.196); catalogued as rs756468291; called by muse, mutect2, varscan2
- CDH8 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 143/511 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54850227; called by muse, mutect2, varscan2
- CDH8 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 114/401 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100184627; called by muse, mutect2, varscan2
- CDH9 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV50290079, COSV99142890; called by muse, mutect2, varscan2
- CELF6 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 56/514 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs1468770954; called by muse, mutect2, varscan2
- CEP120 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs199509467; called by muse, mutect2, varscan2
- CEP131 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 53/531 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs770947504; called by muse, mutect2, varscan2
- CGN | c.876C>T p.F292= | Splice Region (SNP) | VAF 64/299 reads (21%) | catalogued as rs1223304342; called by muse, mutect2, varscan2
- CHD7 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV71112011; called by muse, mutect2, varscan2
- CLEC4D | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202331350, COSV100222853; called by muse, mutect2, varscan2
- CNGB1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs781104590, COSV51901137; ClinVar: uncertain significance; called by muse, mutect2
- CNTN4 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs750294828, COSV61873461; called by muse, mutect2, varscan2
- COL20A1 | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs768405162; called by muse, mutect2, varscan2
- COL28A1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68085104; called by muse, mutect2, varscan2
- COL3A1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1325737333, COSV58584908; called by muse, mutect2, varscan2
- COL8A1 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 127/590 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV53730450; called by muse, mutect2, varscan2
- COL9A1 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881370; called by muse, mutect2, varscan2
- CPA6 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.721); catalogued as COSV52725246; called by muse, varscan2
- CRB1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 59/495 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as rs564754426, COSV66328611; called by muse, mutect2, varscan2
- CREB3L2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 95/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1449053466; called by muse, mutect2, varscan2
- CSMD3 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV99839589; called by muse, mutect2, varscan2
- CSNKA2IP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs935252709, COSV68072668; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 33/340 reads (10%) | catalogued as COSV59088081; called by muse, mutect2
- DCHS1 | c.5132G>A p.R1711Q | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1466443387, COSV55042027; called by muse, mutect2, varscan2
- DCSTAMP | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 119/529 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773599990, COSV52577499, COSV99886910; called by muse, mutect2, varscan2
- DDX23 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.605); catalogued as rs757108543; called by muse, mutect2, varscan2
- DEUP1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53210083; called by muse, mutect2
- DIO3 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 177/568 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.343); catalogued as COSV63774726; called by muse, mutect2, varscan2
- DLGAP1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 53/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234257; called by muse, mutect2
- DNAH8 | c.6694C>T p.R2232C | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868098416, COSV59439250; called by muse, mutect2, varscan2
- DPYSL3 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 34/368 reads (9%) | catalogued as COSV58331681; called by muse, mutect2
- DRICH1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.202); catalogued as rs138414319, COSV58504390; called by muse, varscan2
- DSG2 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 38/411 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs780300040; called by muse, mutect2
- ECE2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs1300018705; called by muse, mutect2, varscan2
- EEFSEC | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV54631877; called by muse, mutect2, varscan2
- EPHA1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 113/591 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs745810214, COSV51971697; called by muse, mutect2, varscan2
- ERBIN | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1296021047; called by muse, mutect2, varscan2
- ESRP1 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329697450; called by muse, mutect2
- FAM170A | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV58926422; called by muse, mutect2, varscan2
- FAM180A | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV58527859, COSV58528579; called by muse, mutect2, varscan2
- FAM222B | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 82/545 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1418739171; called by muse, mutect2, varscan2
- FAT3 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV53094975; called by muse, mutect2
- FBXO11 | c.1745C>T p.P582L (on ENST00000403359 / NM_001190274.2; = p.P498L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/306 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs267599394, COSV57024219; called by muse, mutect2, varscan2
- FHDC1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV52601371; called by muse, mutect2, varscan2
- FSIP2 | c.13567C>T p.R4523* | Nonsense Mutation (SNP) | VAF 47/330 reads (14%) | catalogued as rs776620846; called by muse, mutect2, varscan2
- FYB1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 114/567 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100685526; called by muse, mutect2, varscan2
- GALNT8 | c.1360-1G>A p.X454_splice | Splice Site (SNP) | VAF 20/217 reads (9%) | catalogued as rs202099406, COSV52897392; called by muse, mutect2
- GAST | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 115/446 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs781994438; called by muse, mutect2, varscan2
- GBP5 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV58592505; called by muse, mutect2, varscan2
- GCC1 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 135/626 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs146301759; called by muse, mutect2, varscan2
- GDAP1L1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1201777465; called by muse, mutect2, varscan2
- GEN1 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs771711596; called by muse, mutect2, varscan2
- GPC2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 104/454 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs749760530, COSV52784813; called by muse, mutect2, varscan2
- GRIA1 | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV53630561; called by muse, varscan2
- GRID2 | c.2539T>C p.F847L | Missense Mutation (SNP) | VAF 107/388 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771919836; called by muse, mutect2, varscan2
- GRIN2B | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 112/456 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs868547639; called by muse, mutect2, varscan2
- GUCY1B1 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100025411; called by muse, mutect2, varscan2
- HELZ2 | c.3665C>T p.S1222F (on ENST00000467148 / NM_001037335.2; = p.S653F on NM_033405.3) | Missense Mutation (SNP) | VAF 61/596 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100915533; called by muse, mutect2, varscan2
- HLA-DPA1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1203697225; called by muse, mutect2, varscan2
- HOXB1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 63/485 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs1213632034, COSV53318040; called by muse, mutect2, varscan2
- HSF5 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 90/386 reads (23%) | catalogued as COSV60419477; called by muse, varscan2
- HTN3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as COSV66879496; called by muse, mutect2, varscan2
- HYAL4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 132/502 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV56140734; called by muse, mutect2, varscan2
- HYDIN | c.11228C>T p.P3743L | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV101125043; called by muse, mutect2, varscan2
- IGHA1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 82/874 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774279646; called by muse, mutect2, varscan2
- IGHA2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 128/416 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1555452761; called by muse, mutect2, varscan2
- IGSF1 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs769535778, COSV63836135, COSV63837874; called by muse, mutect2, varscan2
- IL7R | c.1078A>C p.S360R | Missense Mutation (SNP) | VAF 99/541 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57412710; called by muse, mutect2, varscan2
- IMPACT | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV52423272; called by muse, mutect2
- IQCF5 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs1179339007; called by muse, mutect2, varscan2
- IQSEC3 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 121/493 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs781957490, CM142443; called by muse, mutect2, varscan2
- ITGA8 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866292821; called by muse, mutect2, varscan2
- ITGA9 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.443); catalogued as rs556509571, COSV53244885; called by muse, mutect2, varscan2
- KBTBD11 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs746651131, COSV57223655; called by muse, mutect2, varscan2
- KCNC3 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65387433; called by muse, mutect2
- KIRREL2 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 61/461 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99384435; called by muse, mutect2, varscan2
- KLHL33 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 119/481 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196772764; called by muse, mutect2, varscan2
- KRT6A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867635914, COSV58105912; called by muse, mutect2, varscan2
- KRT6C | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs200158036, COSV52878944; called by muse, mutect2
- LAP3 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV56899442; called by muse, mutect2, varscan2
- LEPR | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 114/352 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100847706; called by muse, mutect2, varscan2
- LRBA | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868134041, COSV63965997; called by muse, mutect2
- LRP2 | c.13571C>T p.P4524L | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774971142; called by muse, mutect2, varscan2
- LRP2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55558782; called by muse, mutect2
- LRRC1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63827484, COSV63828772; called by muse, mutect2, varscan2
- LRRC18 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776108946; called by muse, mutect2, varscan2
- LRRC69 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV59256093; called by muse, mutect2
- LRRTM3 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 102/432 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63665904, COSV63669767; called by muse, mutect2, varscan2
- LSP1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 108/538 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs866926158; called by muse, mutect2, varscan2
- LY6H | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 79/818 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1408670857; called by muse, mutect2
- MAMDC4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 63/436 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs759260960; called by muse, mutect2, varscan2
- MAP2 | c.3147A>T p.K1049N | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as rs1353729149; called by mutect2, varscan2
- MAP3K15 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as rs745466888; called by muse, mutect2, varscan2
- MAP4K2 | c.2348G>A p.R783K | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV99581056; called by muse, mutect2, varscan2
- MAPK1IP1L | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 133/473 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.998); catalogued as COSV67106648; called by muse, mutect2, varscan2
- MCCC1 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs748042158, COSV55607378, COSV55610128; called by muse, mutect2, varscan2
- ME1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1024613609, COSV63838552; called by muse, mutect2, varscan2
- MGAT3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.551); catalogued as rs938505781; called by muse, mutect2, varscan2
- MLIP | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51434593; called by muse, mutect2, varscan2
- MOXD1 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100381239; called by muse, mutect2, varscan2
- MPP5 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV55533620; called by muse, mutect2, varscan2
- MRGPRX4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 122/488 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs763831514, COSV58589662; called by muse, mutect2, varscan2
- MSANTD2 | c.1193C>T p.A398V (on ENST00000374979 / NM_001308027.2; = p.A346V on NM_024631.4) | Missense Mutation (SNP) | VAF 116/483 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV99515927; called by muse, mutect2, varscan2
- MSH4 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1279760673, COSV54198748; called by muse, mutect2, varscan2
- MTMR4 | c.2242A>G p.I748V | Missense Mutation (SNP) | VAF 56/436 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1451859955; called by muse, mutect2, varscan2
- MTSS2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 172/466 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV100116361; called by muse, mutect2, varscan2
- MUC16 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV101201045; called by muse, mutect2, varscan2
- MUC5B | c.6758C>T p.S2253F | Missense Mutation (SNP) | VAF 189/877 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1423925216; called by muse, mutect2
- MYBPC2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV63092958; called by muse, mutect2, varscan2
- MYH1 | c.3591G>C p.R1197S | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56845980, COSV56856946; called by muse, mutect2, varscan2
- MYH1 | c.3590G>A p.R1197K | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.85); catalogued as COSV56852504; called by muse, mutect2, varscan2
- MYH4 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs755764532; called by muse, mutect2, varscan2
- MYT1L | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 100/424 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV101220381, COSV67712053; called by muse, varscan2
- NAA25 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV55701918, COSV55708105; called by muse, mutect2, varscan2
- NAT16 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 264/853 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV100296335; called by muse, mutect2, varscan2
- NAV3 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57071784; called by muse, mutect2, varscan2
- NBEA | c.3841C>T p.Q1281* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as COSV59773683; called by muse, mutect2, varscan2
- NCR1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.073); catalogued as COSV52557251; called by muse, mutect2, varscan2
- NIPBL | c.3935T>A p.L1312H | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as CM042512; called by muse, mutect2, varscan2
- NIPBL | c.5801C>T p.T1934I | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as rs773668251; called by muse, mutect2, varscan2
- NKX2-4 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100698623; called by muse, mutect2, varscan2
- NLRP3 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 117/526 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs201377872, COSV100275557; called by muse, mutect2, varscan2
- NME8 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as rs867960102, COSV52249048; called by muse, mutect2, varscan2
- NME8 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs369201077; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NUAK2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 141/503 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1182887357; called by muse, mutect2, varscan2
- NUAK2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV65682938; called by muse, mutect2
- NUP210L | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 37/538 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55157566; called by muse, mutect2
- OPCML | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59456115; called by muse, mutect2, varscan2
- OR10Z1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 112/512 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV63523956; called by muse, mutect2, varscan2
- OR2B11 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1187808268; called by muse, mutect2
- OR4C15 | c.229G>A p.E77K (on ENST00000314644; = p.E23K on NM_001001920.2) | Missense Mutation (SNP) | VAF 87/432 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58951205, COSV58952974; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 101/395 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR5T1 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 72/582 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57302939; called by muse, mutect2, varscan2
- OR6P1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 107/460 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV58110461; called by muse, mutect2, varscan2
- OR8J2 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as rs764161991; called by muse, mutect2
- PALM2AKAP2 | c.53C>T p.S18F (on ENST00000259318 / NM_001136562.3; = p.S249F on NM_007203.5) | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV52175798; called by muse, mutect2, varscan2
- PARM1 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs763364910; called by muse, mutect2, varscan2
- PCBP4 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 75/391 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100436946; called by muse, mutect2, varscan2
- PCDHA2 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 88/648 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs782486996; called by muse, mutect2, varscan2
- PCDHA3 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 73/886 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.031); catalogued as rs1357765961; called by muse, mutect2
- PCDHB7 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.776); catalogued as rs1554279841; called by muse, mutect2, varscan2
- PCDHGA4 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54056472; called by muse, varscan2
- PCDHGA4 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs933117526; called by muse, varscan2
- PCDHGB1 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 130/536 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1367377007; called by muse, mutect2, varscan2
- PCLO | c.4921C>T p.P1641S | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV61665595; called by muse, mutect2
- PGAP1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 97/384 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs936230263, COSV61326009; called by muse, mutect2, varscan2
- PIDD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 67/536 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs777121323; called by muse, mutect2, varscan2
- PLK5 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 65/612 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1445535548; called by muse, mutect2
- PLPPR3 | c.1697C>T p.S566F (on ENST00000520876 / NM_001270366.2; = p.S594F on NM_024888.2) | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV62461544; called by muse, mutect2, varscan2
- PLXNA4 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 92/468 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs376791531; called by muse, mutect2, varscan2
- PPM1F | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 123/561 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs918663158, COSV54283755; called by muse, mutect2, varscan2
- PPP1R13B | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 263/627 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1174165154; called by muse, mutect2, varscan2
- PPP2CB | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 68/272 reads (25%) | catalogued as COSV55329022; called by muse, mutect2, varscan2
- PRB3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.51); catalogued as rs762255184; called by muse, varscan2
- PRKCQ | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54115769; called by muse, mutect2, varscan2
- PRR15L | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1000034933; called by muse, mutect2, varscan2
- PRR30 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 59/546 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV99574540; called by muse, mutect2, varscan2
- PRRC2A | c.5645C>T p.P1882L | Missense Mutation (SNP) | VAF 76/634 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.725); catalogued as rs1432133502; called by mutect2, varscan2
- PSG5 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs3207390, COSV61653524; called by muse, mutect2
- PTCHD3 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as rs764750380, COSV71256257; called by muse, mutect2, varscan2
- PTPRN | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs548633041, COSV55347735, COSV55350153; called by muse, mutect2, varscan2
- PWWP2A | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 103/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100193952; called by muse, mutect2, varscan2
- PXDNL | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 54/610 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1223960216; called by muse, mutect2
- PZP | c.3482C>T p.S1161F | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV54360896; called by muse, mutect2, varscan2
- RECQL5 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 193/620 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as rs964714385; called by muse, mutect2, varscan2
- RGPD1 | c.4132C>T p.R1378C (on ENST00000409776; = p.R1386C on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409111414; called by muse, mutect2, varscan2
- RIOK2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1440501023; called by muse, mutect2, varscan2
- RUFY4 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1277676982; called by muse, mutect2, varscan2
- SCTR | c.405G>A p.R135= | Splice Region (SNP) | VAF 40/312 reads (13%) | catalogued as rs1481285122; called by muse, mutect2, varscan2
- SDK1 | c.6158C>T p.S2053F | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV101269157; called by muse, mutect2
- SGK2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 44/474 reads (9%) | catalogued as rs754924930, COSV58315859; called by muse, mutect2
- SHANK1 | c.5711G>A p.S1904N | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs566966888; called by muse, mutect2, varscan2
- SHANK2 | c.3953C>T p.T1318I | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs971735265; called by muse, mutect2, varscan2
- SHANK2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as rs1555052129; called by muse, mutect2
- SKAP1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 129/424 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.84); catalogued as rs1481579875; called by muse, mutect2, varscan2
- SKAP1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 129/422 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.1); catalogued as rs1317431256, COSV61146830; called by muse, mutect2, varscan2
- SLC4A5 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61031214; called by muse, mutect2, varscan2
- SMAD6 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs752760701; called by muse, mutect2, varscan2
- SMARCA4 | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 66/441 reads (15%) | catalogued as rs1306144699, COSV60797219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC5 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.129); catalogued as COSV63191402; called by muse, mutect2
- SMIM23 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762135201; called by muse, mutect2, varscan2
- SMTNL2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as rs756168695; called by muse, mutect2, varscan2
- SORCS1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 78/591 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs773924138; called by muse, mutect2, varscan2
- SPHKAP | c.3073T>C p.S1025P | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60886822; called by muse, mutect2
- SPTB | c.4292G>A p.R1431Q | Missense Mutation (SNP) | VAF 73/307 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs943876155, COSV67631723; called by muse, mutect2, varscan2
- STARD9 | c.8233C>T p.P2745S | Missense Mutation (SNP) | VAF 59/409 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs961613444; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 117/378 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.803); catalogued as COSV100561815, COSV59129140; called by muse, mutect2, varscan2
- SVEP1 | c.4551G>A p.W1517* | Nonsense Mutation (SNP) | VAF 55/424 reads (13%) | catalogued as COSV57029854; called by muse, mutect2, varscan2
- TAF1L | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 152/533 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs199906668; called by muse, mutect2, varscan2
- TBC1D9 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 35/287 reads (12%) | catalogued as rs916253445, COSV71306874; called by muse, mutect2, varscan2
- TBPL1 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.152); catalogued as rs765137476; called by muse, mutect2, varscan2
- TBR1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV67418022; called by muse, mutect2, varscan2
- TDRD10 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs1184961968; called by muse, mutect2, varscan2
- TET2 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 119/425 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1183128059, COSV54430695; called by muse, mutect2, varscan2
- TEX13C | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.138); catalogued as rs954779606; called by muse, mutect2, varscan2
- THSD7B | c.3349C>T p.P1117S (on ENST00000272643; = p.P1115S on NM_001316349.2) | Missense Mutation (SNP) | VAF 97/456 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV55738693, COSV99758933; called by muse, mutect2, varscan2
- TKT | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 91/400 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782490183, COSV56245433; called by muse, mutect2, varscan2
- TMEM132B | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 124/418 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs781241046, COSV54769432; called by muse, mutect2, varscan2
- TMEM164 | c.541C>G p.H181D (on ENST00000372068 / NM_032227.4; = p.H32D on NM_017698.2) | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55810187; called by muse, mutect2, varscan2
- TMPRSS6 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 55/566 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as COSV60982252; called by muse, mutect2, varscan2
- TNFSF14 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1166721945; called by muse, mutect2, varscan2
- TNXB | c.10268G>A p.G3423E (on ENST00000647633; = p.G3176E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 327/795 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.905); catalogued as COSV64483853; called by muse, mutect2, varscan2
- TONSL | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867459869; called by muse, mutect2
- TRIM55 | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs144861717; called by muse, mutect2, varscan2
- TSPYL6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1309150915, COSV57813155; called by muse, mutect2, varscan2
- TTN | c.35614G>A p.E11872K (on ENST00000591111; = p.E4448K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/290 reads (10%) | PolyPhen probably damaging (0.987); catalogued as COSV59952825; called by muse, mutect2
- UBE3C | c.2984T>G p.V995G | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs773926786; called by muse, mutect2, varscan2
- UGT1A3 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV59381231; called by muse, mutect2, varscan2
- UNC5B | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 140/485 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768380228; called by muse, mutect2, varscan2
- VPS13B | c.6568G>A p.D2190N | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs763541177; called by muse, mutect2, varscan2
- WDR49 | c.1435A>C p.S479R (on ENST00000308378 / NM_001366158.1; = p.S820R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/444 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57705608, COSV57714329; called by muse, mutect2, varscan2
- WNK3 | c.3605G>A p.R1202K | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1557153215; called by muse, mutect2, varscan2
- ZFC3H1 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 90/348 reads (26%) | catalogued as rs1430246426, COSV66430110; called by muse, varscan2
- ZFPM2 | c.3136G>A p.G1046S | Missense Mutation (SNP) | VAF 78/395 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.876); catalogued as rs373369563; called by muse, mutect2, varscan2
- ZIM3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 56/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142195, COSV99517811; called by muse, mutect2, varscan2
- ZNF202 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs770488010, COSV60247992; called by muse, mutect2, varscan2
- ZNF334 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 53/454 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61618072; called by muse, mutect2, varscan2
- ZNF804A | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 45/412 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100167366, COSV100168082; called by muse, mutect2, varscan2
- AASS | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ABCA13 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ABCC10 | c.2174C>T p.T725I (on ENST00000372530 / NM_001198934.2; = p.T697I on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ABCG4 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ABLIM3 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADAM8 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 135/500 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ADAMTS16 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 47/475 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADAMTS9 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 277/511 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- AGBL4 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGFG2 | c.1148T>G p.F383C | Missense Mutation (SNP) | VAF 91/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANGPT4 | c.704C>G p.T235S | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ANK1 | c.3458C>T p.P1153L | Missense Mutation (SNP) | VAF 119/594 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AP000812.4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOBEC3H | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- APOF | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 143/502 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ARHGEF35 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARNT | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASPG | c.83-1G>A p.X28_splice | Splice Site (SNP) | VAF 39/484 reads (8%) | called by muse, mutect2
- ATP10B | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ATRNL1 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- BCOR | c.2860G>T p.V954F | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- BMP6 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.10502C>T p.A3501V | Missense Mutation (SNP) | VAF 67/451 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf38 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C1QTNF2 | c.596T>C p.V199A (on ENST00000393975; = p.V154A on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/577 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- C20orf96 | c.238C>T p.P80S (on ENST00000360321 / NM_153269.3; = p.P79S on NM_080571.1) | Missense Mutation (SNP) | VAF 109/483 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- C9orf131 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 124/473 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C9orf152 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CA13 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 106/442 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CACNA1E | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMK2D | c.819T>C p.C273= | Splice Region (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- CAPN7 | c.2112T>G p.C704W | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCBE1 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 64/451 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC148 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC166 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC7 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CD33 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 54/413 reads (13%) | called by muse, mutect2, varscan2
- CDH10 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 73/437 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CDRT4 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEMIP | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP192 | c.1417T>C p.Y473H | Missense Mutation (SNP) | VAF 30/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CES3 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CFTR | c.54-1G>C p.X18_splice | Splice Site (SNP) | VAF 25/306 reads (8%) | called by muse, mutect2
- CHD8 | c.1072C>T p.P358S (on ENST00000646647 / NM_001170629.2; = p.P79S on NM_020920.4) | Missense Mutation (SNP) | VAF 136/494 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLEC4G | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLTCL1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CMYA5 | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 103/541 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNGB1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- COL2A1 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 52/461 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL6A3 | c.7634G>A p.R2545K | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CORO1A | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRX | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CRYBG2 | c.4602G>A p.W1534* | Nonsense Mutation (SNP) | VAF 33/241 reads (14%) | called by muse, mutect2, varscan2
- CUL9 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 147/495 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYP3A5 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 116/518 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCTN1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DERPC | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DIDO1 | c.6086T>C p.L2029P | Missense Mutation (SNP) | VAF 219/741 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- DLGAP2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DNAH1 | c.7427T>G p.F2476C | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH3 | c.5477C>T p.S1826F | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DSC1 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DSEL | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSG1 | c.3128G>A p.S1043N | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DUSP6 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 89/396 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EDA2R | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EHBP1L1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMID1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 109/654 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTPD5 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA10 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ERG | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ERICH6 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ESPN | c.3456C>A p.H1152Q | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.412); called by muse, mutect2
- ETV5 | c.206T>A p.F69Y | Missense Mutation (SNP) | VAF 126/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EYA4 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- EYA4 | c.1339G>C p.D447H (on ENST00000531901 / NM_001301013.1; = p.D441H on NM_004100.5) | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EYS | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM174C | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- FAT3 | c.834del p.E279Sfs*7 | Frame Shift Del (DEL) | VAF 33/352 reads (9%) | called by pindel, varscan2
- FLG2 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 67/680 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2
- FLNB | c.4100G>A p.G1367E | Missense Mutation (SNP) | VAF 38/854 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMN2 | c.5146G>A p.A1716T | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- FRMD4B | c.1877A>C p.K626T | Missense Mutation (SNP) | VAF 21/751 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- FRMPD1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FSIP2 | c.4500G>A p.M1500I | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FYB1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 125/567 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- GABRB3 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- GANAB | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATAD1 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATB | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI2 | c.4049G>A p.G1350D (on ENST00000361492 / NM_001374353.1; = p.G1367D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/594 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GPR89B | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- GRHL2 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN4 | c.1790C>G p.A597G | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HEATR9 | c.1347C>G p.H449Q | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, varscan2
- HELZ | c.2573G>T p.C858F | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HK2 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 39/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HMGXB3 | c.1826C>T p.S609F (on ENST00000613459; = p.S363F on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.257); called by muse, varscan2
- IQSEC3 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 126/495 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ISLR2 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAD | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JPH2 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 107/471 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KCND2 | c.411C>G p.Y137* | Nonsense Mutation (SNP) | VAF 48/627 reads (8%) | called by muse, mutect2
- KCND3 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KHDRBS2 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549L | c.5201C>T p.S1734F (on ENST00000321505; = p.S2031F on NM_012194.3) | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KMT2D | c.6047C>T p.S2016F | Missense Mutation (SNP) | VAF 75/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KNDC1 | c.3419G>C p.R1140T | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by mutect2, varscan2
- KRT13 | c.1282C>T p.P428S (on ENST00000246635 / NM_153490.3; = p.P419L on NM_002274.4) | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- KRT71 | c.1153A>C p.N385H | Missense Mutation (SNP) | VAF 111/413 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- LGALS2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- LILRB3 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 96/1877 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- LIPN | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- LMTK2 | c.815T>A p.F272Y | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LNPEP | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC1 | c.909C>T p.T303= | Splice Region (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- LRRC24 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 86/671 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC4C | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- LRRN2 | c.1829G>A p.C610Y | Missense Mutation (SNP) | VAF 130/522 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRTM1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 56/556 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP1B | c.3977C>T p.S1326F | Missense Mutation (SNP) | VAF 106/507 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCF2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MDFI | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- MED25 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED7 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MEPCE | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 192/649 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- MGAM | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 83/387 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP16 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 113/542 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP20 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MOV10L1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- MPDZ | c.5605C>T p.P1869S (on ENST00000319217 / NM_001330637.2; = p.P1840S on NM_003829.5) | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MRGPRX3 | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 138/588 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MSTN | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC12 | c.12697A>G p.T4233A (on ENST00000379442; = p.T4090A on NM_001164462.1) | Missense Mutation (SNP) | VAF 186/743 reads (25%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- MUC16 | c.38018C>T p.P12673L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.3887G>A p.R1296K | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC17 | c.7192C>T p.P2398S | Missense Mutation (SNP) | VAF 168/687 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MUC17 | c.11035C>T p.P3679S | Missense Mutation (SNP) | VAF 147/791 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- MUSK | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH4 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- MYO18B | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 40/437 reads (9%) | called by muse, mutect2
- MYO3A | c.4118C>T p.S1373F | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MYRF | c.2028G>A p.M676I (on ENST00000278836 / NM_001127392.3; = p.M667I on NM_013279.4) | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NACC1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 88/517 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- NAV2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 64/274 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NAV2 | c.6469G>A p.G2157S (on ENST00000396087 / NM_001244963.2; = p.G2098S on NM_145117.5) | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV2 | c.6628C>T p.Q2210* (on ENST00000396087 / NM_001244963.2; = p.Q2151* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 43/394 reads (11%) | called by muse, mutect2, varscan2
- NCDN | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK8 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NIBAN2 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NKD2 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NKTR | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRF1 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NRXN2 | c.3589C>T p.Q1197* | Nonsense Mutation (SNP) | VAF 83/341 reads (24%) | called by muse, mutect2, varscan2
- OR10G6 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 112/473 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR10H2 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 57/574 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- OR2Y1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 59/609 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- OR4D9 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR4N2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 92/463 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR52A5 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- OR52E1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- OR52E6 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 114/484 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- OR56B4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OR8D1 | c.416G>A p.W139* | Nonsense Mutation (SNP) | VAF 116/481 reads (24%) | called by muse, mutect2, varscan2
- OTC | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OVGP1 | c.999T>G p.N333K | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- P2RY13 | c.776T>G p.V259G | Missense Mutation (SNP) | VAF 93/413 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PARS2 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHA12 | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 34/328 reads (10%) | called by muse, mutect2, varscan2
- PDE3A | c.1247A>C p.K416T | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PDGFD | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PEX5 | c.1024G>T p.G342W (on ENST00000420616; = p.G334W on NM_000319.5) | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAM2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 126/648 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PHB2 | c.506C>G p.T169R | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PHYHIP | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- PIK3CG | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); called by muse, mutect2
- PIM3 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, varscan2
- PJA2 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2
- PKD1 | c.6089C>T p.P2030L | Missense Mutation (SNP) | VAF 155/569 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKP1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 65/494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLA2G2A | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PLA2G4E | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 135/498 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLA2R1 | c.1913A>G p.K638R | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PM20D1 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PMM1 | c.372G>A p.K124= | Splice Region (SNP) | VAF 26/260 reads (10%) | called by muse, varscan2
- POM121C | c.2869C>T p.P957S (on ENST00000607367; = p.P715S on NM_001099415.3) | Missense Mutation (SNP) | VAF 88/504 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, varscan2
- POU2F1 | c.422C>T p.S141F (on ENST00000541643 / NM_001365848.1; = p.S164F on NM_002697.4) | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PPL | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRAMEF14 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 76/328 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRICKLE2 | c.2228C>T p.S743F (on ENST00000295902; = p.S687F on NM_198859.4) | Missense Mutation (SNP) | VAF 66/1056 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2
- PRPSAP2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR30 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 82/572 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PSPC1 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 33/692 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2
- PXDNL | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RADIL | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 54/575 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMBP3 | c.4393C>T p.P1465S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RIN3 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 90/514 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, varscan2
- RINT1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPOR2 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 58/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- RNF150 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF39 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 68/846 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2
- RNPEP | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNPEP | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPTN | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 162/822 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); called by muse, varscan2
- RWDD3 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 48/454 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- S1PR1 | c.1072T>G p.S358A | Missense Mutation (SNP) | VAF 171/477 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SACS | c.12422T>G p.V4141G | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SCN3A | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SEC24A | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 58/521 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA6B | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SF3A1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 164/519 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SH3PXD2B | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SHOX | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 71/632 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A6 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC16A9 | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC24A3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- SLC47A2 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SLCO2B1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 64/562 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SMARCA2 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SMG7 | c.436T>A p.S146T | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMIM33 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 116/463 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SNAI2 | c.574A>C p.K192Q | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAM1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA16 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 108/395 reads (27%) | called by muse, mutect2, varscan2
- SPOCD1 | c.3056G>A p.G1019E | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SPTBN4 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 58/456 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- STX6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX8 | c.617T>A p.M206K | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5L | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SULF1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- TAF11L2 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 53/545 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2
- TCF20 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 83/541 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TDRKH | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 110/501 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- TECTA | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 89/530 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEKT4 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2
- TEX13C | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TMEM253 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMPRSS6 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 55/563 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TMTC2 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TNS1 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 55/513 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TNS4 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 138/494 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, varscan2
- TPO | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 75/651 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPRX1 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPTE2 | c.1096G>A p.G366R (on ENST00000400230 / NM_199254.2; = p.G289R on NM_130785.3) | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRAV20 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIB3 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 152/690 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- TRIO | c.5213C>T p.S1738F | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIO | c.5288C>T p.S1763L | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRMT2B | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TRPV6 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 56/603 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2
- TTC6 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 106/409 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TUT7 | c.922T>A p.L308I | Missense Mutation (SNP) | VAF 87/419 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- TXNDC16 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- TYW1 | c.1810-1G>A p.X604_splice | Splice Site (SNP) | VAF 25/256 reads (10%) | called by muse, mutect2
- UBR4 | c.10864C>T p.P3622S | Missense Mutation (SNP) | VAF 131/380 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- UBR5 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 100/513 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ULBP3 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USHBP1 | c.1755G>A p.W585* | Nonsense Mutation (SNP) | VAF 39/303 reads (13%) | called by muse, mutect2, varscan2
- USP17L23 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 28/915 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.326); called by muse, mutect2
- USP9X | c.3445C>T p.L1149F | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VCX | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2
- WDFY4 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- WDR87 | c.3279C>T p.S1093= | Splice Region (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- ZBTB20 | c.604C>T p.P202S (on ENST00000474710 / NM_001164342.2; = p.P129S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZCCHC13 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCCHC2 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ZNF229 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF426 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF510 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ZNF560 | c.1877A>C p.K626T | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZNF578 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 48/477 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2
- ZNF585B | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ABCA12 | c.3390C>T p.I1130= (on ENST00000272895 / NM_173076.3; = p.I812= on NM_015657.3) | Silent (SNP) | VAF 49/282 reads (17%) | catalogued as COSV55961218; called by muse, mutect2, varscan2
- ABCA5 | c.651C>T p.P217= | Silent (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
- ABCB1 | c.780A>C p.A260= | Silent (SNP) | VAF 34/398 reads (9%) | called by muse, mutect2
- ADAMTS17 | c.894C>T p.H298= | Silent (SNP) | VAF 87/302 reads (29%) | catalogued as rs757068156; called by muse, mutect2, varscan2
- ADAMTS2 | c.291C>T p.F97= | Silent (SNP) | VAF 200/634 reads (32%) | catalogued as rs462009; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2100G>A p.E700= | Silent (SNP) | VAF 52/373 reads (14%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2217G>A p.K739= | Silent (SNP) | VAF 49/455 reads (11%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2544G>A p.L848= | Silent (SNP) | VAF 46/428 reads (11%) | catalogued as COSV60094056; called by muse, varscan2
- AHNAK | c.3156C>T p.G1052= | Silent (SNP) | VAF 62/554 reads (11%) | catalogued as COSV57205158; called by muse, mutect2, varscan2
- AKAP1 | c.2449C>T p.L817= | Silent (SNP) | VAF 88/358 reads (25%) | called by muse, mutect2, varscan2
- ALPL | c.1167C>T p.T389= | Silent (SNP) | VAF 132/347 reads (38%) | catalogued as rs772412576, COSV100876172; called by muse, mutect2, varscan2
- ANK3 | c.5328C>T p.S1776= | Silent (SNP) | VAF 40/347 reads (12%) | catalogued as rs1406628093, COSV55073860; called by muse, mutect2, varscan2
- APOB | c.9852C>T p.S3284= | Silent (SNP) | VAF 98/412 reads (24%) | called by muse, mutect2, varscan2
- APOB | c.147C>T p.L49= | Silent (SNP) | VAF 23/309 reads (7%) | called by muse, mutect2
- ARHGEF17 | c.3648C>T p.Y1216= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as rs756108203, COSV55229164; called by muse, mutect2
- ARID1A | c.6462C>T p.F2154= | Silent (SNP) | VAF 66/503 reads (13%) | called by muse, mutect2, varscan2
- ARID5A | c.790C>T p.L264= | Silent (SNP) | VAF 66/549 reads (12%) | called by muse, mutect2, varscan2
- ATP1A3 | c.435C>T p.I145= (on ENST00000545399 / NM_001256214.2; = p.I132= on NM_152296.5) | Silent (SNP) | VAF 32/246 reads (13%) | called by muse, mutect2, varscan2
- BHMT2 | c.693G>A p.L231= | Silent (SNP) | VAF 57/535 reads (11%) | called by muse, mutect2, varscan2
- BRCA2 | c.9162C>T p.P3054= | Silent (SNP) | VAF 44/400 reads (11%) | catalogued as rs778426874; ClinVar: likely benign; called by muse, mutect2
- C6 | c.1311A>C p.A437= | Silent (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- C7orf61 | c.135G>A p.K45= | Silent (SNP) | VAF 98/528 reads (19%) | called by muse, varscan2
- C8orf82 | c.36C>T p.A12= | Silent (SNP) | VAF 62/600 reads (10%) | catalogued as rs1419940273; called by muse, mutect2, varscan2
- CA13 | c.249T>C p.G83= | Silent (SNP) | VAF 86/395 reads (22%) | catalogued as rs369383126; called by muse, mutect2, varscan2
- CASP14 | c.411G>A p.R137= | Silent (SNP) | VAF 34/274 reads (12%) | called by muse, mutect2, varscan2
- CCDC54 | c.69G>A p.K23= | Silent (SNP) | VAF 55/458 reads (12%) | catalogued as rs755943466; called by muse, mutect2, varscan2
- CCDC88C | c.5976C>T p.L1992= | Silent (SNP) | VAF 71/513 reads (14%) | catalogued as rs771889634, COSV57797357; called by muse, mutect2, varscan2
- CD1B | c.93C>T p.I31= | Silent (SNP) | VAF 98/436 reads (22%) | catalogued as rs1282790491, COSV100939164, COSV100939254; called by muse, mutect2, varscan2
- CDC42EP5 | c.81C>T p.L27= | Silent (SNP) | VAF 67/415 reads (16%) | called by muse, varscan2
- CDK4 | c.69C>T p.A23= | Silent (SNP) | VAF 100/378 reads (26%) | called by muse, mutect2, varscan2
- CELF6 | c.915C>T p.T305= | Silent (SNP) | VAF 59/519 reads (11%) | catalogued as rs1234848582; called by muse, mutect2, varscan2
- CFAP61 | c.1281C>T p.L427= | Silent (SNP) | VAF 40/454 reads (9%) | catalogued as rs756282986; called by muse, mutect2
- CHIT1 | c.1026C>T p.T342= | Silent (SNP) | VAF 39/333 reads (12%) | catalogued as rs1461866956; called by muse, mutect2, varscan2
- CHST1 | c.646C>T p.L216= | Silent (SNP) | VAF 63/670 reads (9%) | catalogued as rs752313786; called by muse, mutect2
- CIC | c.402C>T p.P134= | Silent (SNP) | VAF 74/441 reads (17%) | called by muse, mutect2, varscan2
- CLCN1 | c.2517C>T p.T839= | Silent (SNP) | VAF 91/404 reads (23%) | called by muse, mutect2, varscan2
- CLDN17 | c.229C>T p.L77= | Silent (SNP) | VAF 50/424 reads (12%) | catalogued as COSV99729137; called by muse, varscan2
- CLSPN | c.2583C>T p.F861= | Silent (SNP) | VAF 67/365 reads (18%) | called by muse, mutect2, varscan2
- CNGB1 | c.2580C>T p.F860= | Silent (SNP) | VAF 91/358 reads (25%) | catalogued as COSV51900275; called by muse, mutect2, varscan2
- CRKL | c.15G>A p.R5= | Silent (SNP) | VAF 52/618 reads (8%) | called by muse, mutect2
- CYP11B2 | c.543G>A p.R181= | Silent (SNP) | VAF 112/591 reads (19%) | called by muse, mutect2, varscan2
- CYP1A1 | c.1281C>T p.F427= | Silent (SNP) | VAF 37/316 reads (12%) | catalogued as rs375950006, COSV101122335; called by muse, mutect2, varscan2
- CYP24A1 | c.165G>A p.A55= | Silent (SNP) | VAF 66/602 reads (11%) | catalogued as rs1214111067; called by muse, mutect2, varscan2
- CYP2A13 | c.453G>A p.E151= | Silent (SNP) | VAF 50/399 reads (13%) | called by muse, mutect2, varscan2
- CYP2A13 | c.789C>T p.S263= | Silent (SNP) | VAF 61/483 reads (13%) | catalogued as rs1341782955, COSV57837368; called by muse, mutect2, varscan2
- CYP3A5 | c.1134G>A p.K378= | Silent (SNP) | VAF 54/552 reads (10%) | called by muse, mutect2
- CYP3A5 | c.612G>A p.V204= | Silent (SNP) | VAF 116/520 reads (22%) | called by muse, mutect2, varscan2
- DCC | c.1680T>C p.G560= | Silent (SNP) | VAF 47/366 reads (13%) | called by muse, mutect2, varscan2
- DCLK1 | c.243C>T p.F81= | Silent (SNP) | VAF 53/488 reads (11%) | called by muse, mutect2, varscan2
- DENND6A | c.1086C>T p.L362= | Silent (SNP) | VAF 46/804 reads (6%) | catalogued as COSV60767677; called by muse, mutect2
- DHX34 | c.1551C>T p.V517= | Silent (SNP) | VAF 54/455 reads (12%) | catalogued as rs773187359; called by muse, mutect2, varscan2
- DNAH11 | c.5694G>A p.G1898= | Silent (SNP) | VAF 65/396 reads (16%) | called by muse, mutect2, varscan2
- DNAH2 | c.7810C>T p.L2604= | Silent (SNP) | VAF 90/331 reads (27%) | called by muse, mutect2, varscan2
- DNAH5 | c.11715C>T p.I3905= | Silent (SNP) | VAF 91/382 reads (24%) | called by muse, mutect2, varscan2
- DNAH8 | c.1224G>A p.K408= | Silent (SNP) | VAF 62/276 reads (22%) | called by muse, mutect2, varscan2
- DNAH9 | c.7218C>T p.F2406= | Silent (SNP) | VAF 38/382 reads (10%) | called by muse, mutect2
- DNALI1 | c.138G>A p.R46= (on ENST00000296218; = p.R24= on NM_003462.5) | Silent (SNP) | VAF 55/222 reads (25%) | called by muse, mutect2, varscan2
- DNPEP | c.597C>T p.P199= | Silent (SNP) | VAF 37/350 reads (11%) | called by muse, mutect2, varscan2
- DSCAM | c.5202G>A p.R1734= | Silent (SNP) | VAF 46/327 reads (14%) | catalogued as rs777965263, COSV68037693; called by muse, mutect2, varscan2
- EFCAB12 | c.1713C>T p.I571= | Silent (SNP) | VAF 39/353 reads (11%) | called by muse, mutect2, varscan2
- EGFR | c.3465C>T p.A1155= | Silent (SNP) | VAF 109/543 reads (20%) | called by muse, mutect2, varscan2
- EML5 | c.4047G>A p.Q1349= (on ENST00000380664; = p.Q1357= on NM_183387.3) | Silent (SNP) | VAF 85/314 reads (27%) | called by muse, mutect2, varscan2
- EPHA3 | c.426G>A p.K142= | Silent (SNP) | VAF 94/429 reads (22%) | called by muse, mutect2, varscan2
- EPHB4 | c.2238C>T p.I746= | Silent (SNP) | VAF 80/491 reads (16%) | called by muse, mutect2, varscan2
- ERC2 | c.24C>T p.I8= | Silent (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- EXOC3L2 | c.228G>A p.R76= | Silent (SNP) | VAF 62/465 reads (13%) | called by muse, mutect2, varscan2
- FAM160A2 | c.978C>T p.I326= | Silent (SNP) | VAF 46/461 reads (10%) | catalogued as rs778952177; called by muse, mutect2
- FRMPD4 | c.3336G>A p.G1112= | Silent (SNP) | VAF 64/336 reads (19%) | catalogued as COSV66215218; called by muse, mutect2, varscan2
- GAST | c.141G>A p.L47= | Silent (SNP) | VAF 116/449 reads (26%) | called by muse, mutect2, varscan2
- GGACT | c.15C>T p.F5= | Silent (SNP) | VAF 58/371 reads (16%) | catalogued as rs1315552760, COSV100883641; called by muse, mutect2, varscan2
- GML | c.415C>T p.L139= | Silent (SNP) | VAF 82/419 reads (20%) | called by muse, mutect2, varscan2
- GPI | c.1224C>T p.I408= | Silent (SNP) | VAF 55/356 reads (15%) | called by muse, mutect2, varscan2
- GRIFIN | c.231G>A p.L77= | Silent (SNP) | VAF 76/404 reads (19%) | called by muse, mutect2, varscan2
- GRIP2 | c.1491C>T p.A497= (on ENST00000619221; = p.A400= on NM_001080423.4) | Silent (SNP) | VAF 48/321 reads (15%) | called by muse, mutect2, varscan2
- GRK2 | c.339C>T p.I113= | Silent (SNP) | VAF 82/370 reads (22%) | called by muse, mutect2, varscan2
- GRK2 | c.1764C>T p.L588= | Silent (SNP) | VAF 52/536 reads (10%) | catalogued as rs766428521; called by muse, mutect2
- GSDMD | c.156C>T p.P52= | Silent (SNP) | VAF 124/632 reads (20%) | called by muse, varscan2
- GUCY2C | c.2094C>T p.S698= | Silent (SNP) | VAF 84/278 reads (30%) | catalogued as COSV53794834; called by muse, mutect2, varscan2
- H6PD | c.1110G>A p.R370= | Silent (SNP) | VAF 73/448 reads (16%) | catalogued as COSV66232015; called by muse, mutect2, varscan2
- IFT52 | c.804C>T p.T268= | Silent (SNP) | VAF 80/455 reads (18%) | called by muse, mutect2, varscan2
- IFT52 | c.805C>T p.L269= | Silent (SNP) | VAF 80/458 reads (17%) | called by muse, mutect2, varscan2
- IGHG4 | c.840C>T p.S280= | Silent (SNP) | VAF 223/1159 reads (19%) | catalogued as rs587731180; called by muse, mutect2, varscan2
- IGHM | c.690C>T p.S230= | Silent (SNP) | VAF 39/331 reads (12%) | called by muse, mutect2, varscan2
- IGLV4-60 | c.24C>T p.L8= | Silent (SNP) | VAF 119/914 reads (13%) | catalogued as rs1259982544, COSV66503563; called by muse, mutect2, varscan2
- IGSF9 | c.1677C>T p.S559= (on ENST00000368094 / NM_001135050.2; = p.S543= on NM_020789.4) | Silent (SNP) | VAF 157/599 reads (26%) | catalogued as rs765797057, COSV63642068; called by muse, mutect2, varscan2
- IL31RA | c.2191C>T p.L731= | Silent (SNP) | VAF 44/533 reads (8%) | called by muse, mutect2
- IMPG1 | c.363G>A p.G121= | Silent (SNP) | VAF 91/400 reads (23%) | catalogued as rs1471192965; called by muse, mutect2, varscan2
- INSRR | c.3846A>C p.S1282= | Silent (SNP) | VAF 120/581 reads (21%) | called by muse, mutect2, varscan2
- IQGAP2 | c.588C>T p.F196= | Silent (SNP) | VAF 41/355 reads (12%) | catalogued as rs1260354441; called by muse, mutect2, varscan2
- IRAG2 | c.15G>A p.R5= | Silent (SNP) | VAF 54/243 reads (22%) | called by muse, mutect2, varscan2
- KCNB1 | c.903C>T p.I301= | Silent (SNP) | VAF 62/763 reads (8%) | catalogued as rs1441724609; called by muse, mutect2
- KCNQ4 | c.1809G>A p.G603= | Silent (SNP) | VAF 109/450 reads (24%) | catalogued as rs1403519850; called by muse, mutect2, varscan2
- KIAA2026 | c.4188C>T p.P1396= | Silent (SNP) | VAF 56/389 reads (14%) | catalogued as rs772745862; called by muse, mutect2, varscan2
- KIF26A | c.2523C>T p.F841= | Silent (SNP) | VAF 268/605 reads (44%) | catalogued as rs748280823, COSV59466061; called by muse, mutect2, varscan2
- KLHL30 | c.843G>A p.E281= | Silent (SNP) | VAF 78/499 reads (16%) | called by muse, mutect2, varscan2
- KLHL35 | c.1740C>T p.S580= | Silent (SNP) | VAF 44/360 reads (12%) | called by muse, mutect2, varscan2
- LCE1D | c.132C>T p.S44= | Silent (SNP) | VAF 171/388 reads (44%) | catalogued as rs753178521, COSV100405900; called by muse, mutect2, varscan2
- LECT2 | c.21C>T p.L7= | Silent (SNP) | VAF 76/336 reads (23%) | called by muse, mutect2, varscan2
- LGALS3BP | c.1347C>T p.A449= | Silent (SNP) | VAF 126/452 reads (28%) | called by muse, mutect2, varscan2
- LPO | c.579G>A p.R193= | Silent (SNP) | VAF 33/263 reads (13%) | catalogued as COSV51862369; called by muse, mutect2, varscan2
- LRRIQ1 | c.2706C>T p.F902= | Silent (SNP) | VAF 62/294 reads (21%) | catalogued as rs1396830568; called by muse, mutect2
- MAB21L1 | c.966G>A p.P322= | Silent (SNP) | VAF 40/354 reads (11%) | catalogued as rs1315099268, COSV59774085; called by muse, mutect2, varscan2
- MAGEL2 | c.1962C>T p.P654= | Silent (SNP) | VAF 125/562 reads (22%) | catalogued as COSV100046011; called by muse, mutect2, varscan2
- MAGI2 | c.3639C>T p.L1213= | Silent (SNP) | VAF 60/594 reads (10%) | catalogued as COSV62634902; called by muse, mutect2, varscan2
- MAN1B1 | c.1233C>T p.L411= | Silent (SNP) | VAF 77/368 reads (21%) | called by muse, mutect2, varscan2
- MCEMP1 | c.384C>T p.S128= | Silent (SNP) | VAF 35/303 reads (12%) | catalogued as rs1411645538, COSV100365419; called by muse, mutect2, varscan2
- MCTP1 | c.858G>A p.V286= | Silent (SNP) | VAF 74/247 reads (30%) | catalogued as COSV56510744; called by muse, mutect2, varscan2
- MCTP2 | c.2094G>A p.L698= | Silent (SNP) | VAF 86/241 reads (36%) | called by muse, mutect2, varscan2
- MEGF6 | c.3165C>T p.D1055= | Silent (SNP) | VAF 62/431 reads (14%) | called by muse, mutect2, varscan2
- MEP1A | c.972G>A p.A324= | Silent (SNP) | VAF 68/277 reads (25%) | catalogued as rs1284691696, COSV57920156, COSV57921959; called by muse, mutect2, varscan2
- MIXL1 | c.504G>A p.T168= | Silent (SNP) | VAF 43/397 reads (11%) | catalogued as COSV64729115; called by muse, mutect2, varscan2
- MLLT1 | c.310C>T p.L104= | Silent (SNP) | VAF 60/405 reads (15%) | called by muse, mutect2, varscan2
- MRI1 | c.453C>T p.L151= | Silent (SNP) | VAF 66/478 reads (14%) | catalogued as rs770138569; called by muse, mutect2, varscan2
- MTSS2 | c.324G>A p.Q108= | Silent (SNP) | VAF 172/466 reads (37%) | catalogued as rs1469834376; called by muse, mutect2, varscan2
- MUC16 | c.28065C>T p.T9355= | Silent (SNP) | VAF 81/471 reads (17%) | catalogued as COSV101198338; called by muse, mutect2, varscan2
- MUC16 | c.17460C>T p.I5820= | Silent (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
- MYH15 | c.4033C>T p.L1345= | Silent (SNP) | VAF 87/373 reads (23%) | called by muse, mutect2, varscan2
- MYH2 | c.2517C>T p.F839= | Silent (SNP) | VAF 83/357 reads (23%) | catalogued as rs1489105001; called by muse, mutect2, varscan2
- MYOM3 | c.2316C>T p.F772= | Silent (SNP) | VAF 30/368 reads (8%) | called by muse, mutect2
- MYT1L | c.1101C>T p.F367= | Silent (SNP) | VAF 54/460 reads (12%) | called by muse, varscan2
- N4BP2 | c.4881C>T p.F1627= | Silent (SNP) | VAF 101/411 reads (25%) | called by muse, mutect2, varscan2
- NAV2 | c.5952C>T p.L1984= (on ENST00000396087 / NM_001244963.2; = p.L1925= on NM_145117.5) | Silent (SNP) | VAF 43/416 reads (10%) | catalogued as rs967366138; called by muse, mutect2, varscan2
- NCKAP5 | c.1086G>A p.R362= | Silent (SNP) | VAF 64/274 reads (23%) | called by muse, mutect2, varscan2
- NCMAP | c.216C>T p.T72= | Silent (SNP) | VAF 71/453 reads (16%) | catalogued as rs373926438; called by muse, mutect2, varscan2
- NCOA2 | c.2964C>T p.I988= | Silent (SNP) | VAF 48/457 reads (11%) | called by muse, mutect2, varscan2
- NEB | c.17548C>T p.L5850= | Silent (SNP) | VAF 76/357 reads (21%) | catalogued as rs776071706; called by muse, mutect2, varscan2
- NEXMIF | c.783C>T p.F261= | Silent (SNP) | VAF 48/263 reads (18%) | catalogued as rs768534908, COSV50022266; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP13 | c.1590T>G p.G530= | Silent (SNP) | VAF 60/441 reads (14%) | called by muse, mutect2, varscan2
- NLRP3 | c.1353C>T p.P451= | Silent (SNP) | VAF 115/524 reads (22%) | catalogued as rs200228309, COSV60229163; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOP53 | c.1149G>A p.A383= | Silent (SNP) | VAF 102/713 reads (14%) | catalogued as rs747612737, COSV99884694; called by muse, mutect2
- NOP56 | c.675G>A p.E225= | Silent (SNP) | VAF 89/488 reads (18%) | catalogued as rs763834414; called by muse, mutect2, varscan2
- NOVA2 | c.576C>T p.A192= | Silent (SNP) | VAF 68/414 reads (16%) | called by muse, varscan2
- NR1H2 | c.36C>T p.P12= | Silent (SNP) | VAF 65/417 reads (16%) | called by muse, mutect2, varscan2
- NR1H4 | c.585G>A p.R195= (on ENST00000551379 / NM_001206993.2; = p.R185= on NM_005123.4) | Silent (SNP) | VAF 37/359 reads (10%) | catalogued as COSV51853845; called by muse, mutect2, varscan2
- NTSR1 | c.1191G>A p.R397= | Silent (SNP) | VAF 46/550 reads (8%) | called by muse, mutect2
- NWD1 | c.1956C>T p.L652= | Silent (SNP) | VAF 43/327 reads (13%) | catalogued as rs1357958724; called by muse, mutect2, varscan2
- OR2A14 | c.138G>A p.G46= | Silent (SNP) | VAF 92/490 reads (19%) | called by muse, mutect2, varscan2
- OR2A5 | c.861C>T p.P287= | Silent (SNP) | VAF 78/437 reads (18%) | called by mutect2, varscan2
- OR52A5 | c.486A>G p.L162= | Silent (SNP) | VAF 50/398 reads (13%) | called by muse, mutect2, varscan2
- OR56B4 | c.33C>T p.S11= | Silent (SNP) | VAF 34/310 reads (11%) | called by muse, mutect2, varscan2
- OR5AS1 | c.375C>A p.A125= | Silent (SNP) | VAF 48/468 reads (10%) | catalogued as COSV57983320; called by muse, mutect2, varscan2
- OR6C3 | c.69G>A p.V23= | Silent (SNP) | VAF 66/296 reads (22%) | catalogued as COSV65570612; called by muse, mutect2, varscan2
- OR6M1 | c.525C>T p.F175= | Silent (SNP) | VAF 114/417 reads (27%) | called by muse, mutect2, varscan2
- OR8I2 | c.339C>T p.F113= | Silent (SNP) | VAF 49/450 reads (11%) | catalogued as COSV56167742; called by muse, mutect2, varscan2
- OTOP1 | c.363C>T p.F121= | Silent (SNP) | VAF 114/379 reads (30%) | called by muse, mutect2, varscan2
- OTOP3 | c.315C>T p.I105= | Silent (SNP) | VAF 174/499 reads (35%) | called by muse, mutect2, varscan2
- P2RY8 | c.669G>A p.T223= | Silent (SNP) | VAF 168/827 reads (20%) | catalogued as rs370852351, COSV101183981; called by muse, mutect2, varscan2
- PAPPA | c.2580G>A p.E860= | Silent (SNP) | VAF 135/482 reads (28%) | catalogued as rs759897818; called by muse, mutect2, varscan2
- PARD6G | c.426C>T p.P142= | Silent (SNP) | VAF 59/506 reads (12%) | catalogued as rs768300051; called by muse, mutect2, varscan2
- PCARE | c.1782C>T p.S594= | Silent (SNP) | VAF 145/450 reads (32%) | called by muse, mutect2, varscan2
- PCBP4 | c.477C>T p.I159= | Silent (SNP) | VAF 99/464 reads (21%) | catalogued as rs771781741; called by muse, mutect2, varscan2
- PCDH9 | c.3105C>T p.F1035= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- PCDHA8 | c.726C>T p.F242= | Silent (SNP) | VAF 64/487 reads (13%) | catalogued as rs782260915, COSV65334652; called by muse, mutect2, varscan2
- PCDHB11 | c.586C>T p.L196= | Silent (SNP) | VAF 54/473 reads (11%) | catalogued as rs1358552480; called by muse, mutect2, varscan2
- PCDHB2 | c.2013C>T p.P671= | Silent (SNP) | VAF 76/772 reads (10%) | catalogued as COSV50638960; called by muse, mutect2, varscan2
- PCDHGA10 | c.645C>T p.V215= | Silent (SNP) | VAF 117/571 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.435C>T p.I145= | Silent (SNP) | VAF 48/422 reads (11%) | catalogued as rs1242966092, COSV53921889; called by muse, mutect2, varscan2
- PDGFRL | c.1047G>A p.T349= | Silent (SNP) | VAF 44/425 reads (10%) | catalogued as rs140040139; called by muse, mutect2, varscan2
- PGGHG | c.1836C>T p.D612= | Silent (SNP) | VAF 43/391 reads (11%) | catalogued as rs371413879; called by muse, mutect2, varscan2
- PHLPP2 | c.2184C>T p.I728= | Silent (SNP) | VAF 80/283 reads (28%) | catalogued as rs1567613349, COSV62425833; called by muse, mutect2, varscan2
- PHTF1 | c.597T>G p.G199= | Silent (SNP) | VAF 93/238 reads (39%) | catalogued as rs762534556, COSV63367758; called by mutect2, varscan2
- PI4KA | c.5982C>T p.I1994= | Silent (SNP) | VAF 114/660 reads (17%) | called by muse, mutect2, varscan2
- PIEZO2 | c.3546C>T p.F1182= | Silent (SNP) | VAF 181/500 reads (36%) | catalogued as COSV100126088; called by muse, mutect2, varscan2
- PITPNM1 | c.1290C>T p.F430= | Silent (SNP) | VAF 131/509 reads (26%) | catalogued as COSV62708752; called by muse, mutect2, varscan2
- PITPNM1 | c.618C>T p.I206= | Silent (SNP) | VAF 28/346 reads (8%) | catalogued as rs1231768418, COSV100039288; called by muse, mutect2
- PLCG1 | c.3870C>T p.L1290= (on ENST00000373271 / NM_182811.2; = p.L1291= on NM_002660.3) | Silent (SNP) | VAF 46/463 reads (10%) | catalogued as rs200738304; called by muse, mutect2
- POLM | c.1260A>G p.V420= | Silent (SNP) | VAF 112/578 reads (19%) | called by muse, mutect2, varscan2
- POLQ | c.6829C>T p.L2277= | Silent (SNP) | VAF 32/269 reads (12%) | called by muse, mutect2, varscan2
- POLQ | c.6828C>T p.G2276= | Silent (SNP) | VAF 32/270 reads (12%) | called by muse, mutect2, varscan2
- POTEE | c.2298C>T p.T766= | Silent (SNP) | VAF 36/443 reads (8%) | called by muse, mutect2, varscan2
- POTEJ | c.2613C>T p.I871= | Silent (SNP) | VAF 103/641 reads (16%) | catalogued as rs764884437; called by muse, mutect2, varscan2
- PPP4R1 | c.1617G>A p.L539= (on ENST00000400556 / NM_001042388.3; = p.L522= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/500 reads (8%) | called by muse, mutect2
- PRKDC | c.3669C>G p.T1223= | Silent (SNP) | VAF 42/365 reads (12%) | catalogued as COSV100044137; called by muse, mutect2, varscan2
- PRPH2 | c.408C>T p.N136= | Silent (SNP) | VAF 60/447 reads (13%) | catalogued as rs148513859; called by muse, mutect2, varscan2
- PRR15L | c.165G>A p.L55= | Silent (SNP) | VAF 57/526 reads (11%) | called by muse, mutect2, varscan2
- PRRC2B | c.5037T>A p.S1679= | Silent (SNP) | VAF 101/383 reads (26%) | called by muse, mutect2, varscan2
- PRSS45P | c.195G>A p.R65= | Silent (SNP) | VAF 52/340 reads (15%) | called by muse, mutect2, varscan2
- PSMC2 | c.1227C>T p.F409= | Silent (SNP) | VAF 85/468 reads (18%) | called by muse, mutect2, varscan2
- PTPRB | c.2307A>G p.K769= | Silent (SNP) | VAF 46/381 reads (12%) | called by muse, mutect2, varscan2
- PXDNL | c.1620C>T p.P540= | Silent (SNP) | VAF 41/311 reads (13%) | called by muse, mutect2, varscan2
- PZP | c.2913C>T p.L971= | Silent (SNP) | VAF 43/328 reads (13%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.3489C>T p.C1163= | Silent (SNP) | VAF 58/387 reads (15%) | catalogued as rs967925491; called by muse, mutect2, varscan2
- RECQL5 | c.2205C>T p.S735= | Silent (SNP) | VAF 191/621 reads (31%) | called by muse, mutect2, varscan2
- RGL1 | c.2037C>T p.I679= (on ENST00000360851 / NM_001297672.2; = p.I714= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/342 reads (20%) | catalogued as COSV100486342; called by muse, mutect2, varscan2
- RNF123 | c.1233C>T p.I411= | Silent (SNP) | VAF 52/323 reads (16%) | called by muse, mutect2, varscan2
- RNF123 | c.1234C>T p.L412= | Silent (SNP) | VAF 51/322 reads (16%) | catalogued as COSV100571012; called by muse, mutect2, varscan2
- RNF150 | c.165C>T p.P55= | Silent (SNP) | VAF 91/401 reads (23%) | catalogued as rs762512426, COSV60787416; called by muse, mutect2, varscan2
- ROR1 | c.351G>A p.R117= | Silent (SNP) | VAF 110/441 reads (25%) | catalogued as rs755809255, COSV64291847; called by muse, mutect2, varscan2
- RUVBL2 | c.330C>T p.S110= | Silent (SNP) | VAF 49/443 reads (11%) | catalogued as rs746395753; called by muse, mutect2, varscan2
- SCARA5 | c.742C>T p.L248= | Silent (SNP) | VAF 70/489 reads (14%) | catalogued as rs1260433461; called by muse, mutect2, varscan2
- SCN10A | c.4965C>T p.F1655= | Silent (SNP) | VAF 56/421 reads (13%) | catalogued as COSV71861765; called by muse, mutect2, varscan2
- SCN9A | c.5373C>T p.P1791= (on ENST00000303354; = p.P1780= on NM_002977.3) | Silent (SNP) | VAF 102/465 reads (22%) | catalogued as rs986047440, COSV57608727; called by muse, mutect2, varscan2
- SETD1A | c.4593C>G p.R1531= | Silent (SNP) | VAF 33/379 reads (9%) | called by muse, mutect2
- SGSM3 | c.1827C>T p.S609= | Silent (SNP) | VAF 47/356 reads (13%) | catalogued as rs1569228535, COSV50651788; called by muse, mutect2, varscan2
- SHISA4 | c.267C>T p.I89= | Silent (SNP) | VAF 37/313 reads (12%) | catalogued as rs763815716, COSV62884697; called by muse, mutect2, varscan2
- SHOX | c.843C>T p.L281= | Silent (SNP) | VAF 42/434 reads (10%) | called by muse, mutect2
- SIRPD | c.306C>T p.T102= | Silent (SNP) | VAF 102/521 reads (20%) | catalogued as rs1343808689, COSV67546470; called by muse, mutect2, varscan2
- SLC10A4 | c.408C>T p.P136= | Silent (SNP) | VAF 59/397 reads (15%) | called by muse, mutect2, varscan2
- SLC26A4 | c.486C>T p.L162= | Silent (SNP) | VAF 69/394 reads (18%) | catalogued as rs370020280, COSV55917685; called by muse, mutect2, varscan2
- SLC29A2 | c.1329C>T p.S443= | Silent (SNP) | VAF 54/380 reads (14%) | called by muse, mutect2, varscan2
- SLC38A10 | c.2634C>T p.F878= | Silent (SNP) | VAF 311/665 reads (47%) | called by muse, mutect2, varscan2
- SLC38A8 | c.297C>T p.A99= | Silent (SNP) | VAF 66/471 reads (14%) | catalogued as rs1233756361; called by muse, mutect2, varscan2
- SLC9C2 | c.1992G>A p.R664= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1326C>T p.V442= | Silent (SNP) | VAF 72/341 reads (21%) | catalogued as COSV101134215; called by muse, mutect2, varscan2
- SMC5 | c.411C>T p.T137= | Silent (SNP) | VAF 82/269 reads (30%) | called by muse, mutect2, varscan2
- SMIM21 | c.87G>A p.R29= | Silent (SNP) | VAF 42/285 reads (15%) | called by muse, mutect2, varscan2
- SMIM33 | c.228C>T p.L76= | Silent (SNP) | VAF 115/456 reads (25%) | called by muse, mutect2, varscan2
- SNCAIP | c.1156T>C p.L386= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as rs766152761; called by muse, mutect2, varscan2
- SOWAHD | c.732A>G p.E244= | Silent (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- SP100 | c.2385C>T p.F795= | Silent (SNP) | VAF 39/318 reads (12%) | catalogued as rs543288909, COSV60844606; called by muse, mutect2, varscan2
75 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 29 other) are not listed here.
